Somatic mutation profile of tumor specimen MMRF_1500_1_BM_CD138pos (aliquot MMRF_1500_1_BM_CD138pos_T1_KBS5U_L05838) from MMRF case MMRF_1500, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.4 years (22,054 days).
Specimen MMRF_1500_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 882afd39-04df-4c25-ae7b-d7b4aac7d203.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1500_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1500_2_PB_WBC_C3_KHS5U_L14854; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e255ec0-d0d2-4977-a907-b77063202907

The open-access MAF lists 111 somatic variants for this specimen: 54 protein-altering or splice-affecting, 8 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, 3'UTR 30, Intron 12, Silent 8, 5'Flank 3, 3'Flank 3, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.2594G>A p.R865Q (on ENST00000614293; = p.R835Q on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs201546770, COSV99688678; called by muse, mutect2, varscan2
- ARHGAP19 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 45/126 reads (36%) | catalogued as rs751754099; called by muse, mutect2, varscan2
- CEP70 | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV53875159; called by muse, mutect2
- DNAAF3 | c.164T>C p.V55A (on ENST00000524407 / NM_001256715.2; = p.V102A on NM_178837.4) | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.722); catalogued as rs761210447; called by muse, mutect2, varscan2
- FAM83G | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370774339; called by muse, mutect2, varscan2
- GALNTL6 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs146548110, COSV72490733, COSV72495008; called by muse, mutect2, varscan2
- IGHV3-23 | c.217A>G p.S73G | Missense Mutation (SNP) | VAF 68/366 reads (19%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs571928197; called by muse, varscan2
- IGHV3-23 | c.152A>C p.Y51S | Missense Mutation (SNP) | VAF 54/291 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.033); catalogued as rs183319819; called by muse, varscan2
- IPCEF1 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1276311719; called by muse, mutect2, varscan2
- ITIH6 | c.1207G>A p.G403S | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.12); PolyPhen benign (0.376); catalogued as rs747260784, COSV54492091; called by muse, mutect2, varscan2
- OR51E1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.54); catalogued as rs575981363, COSV67809895; called by muse, mutect2, varscan2
- QSER1 | c.854C>T p.T285I (on ENST00000399302; = p.T414I on NM_001076786.3) | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs79552406, COSV67901350; called by muse, mutect2, varscan2
- RGS22 | c.3109C>T p.R1037C | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs370385204; called by muse, mutect2, varscan2
- SOCS1 | c.184G>C p.A62P | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.681); catalogued as COSV59659669; called by muse, mutect2, varscan2
- SUPT5H | c.2638G>A p.G880R | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as COSV100781983; called by muse, mutect2, varscan2
- TDRD6 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as rs766526554; called by muse, varscan2
- TMEM168 | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as rs755373271, COSV57181281; called by muse, mutect2, varscan2
- ZC3H3 | c.325C>A p.H109N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as rs183380208; called by muse, mutect2, varscan2
- ZNF616 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs750332191; called by muse, mutect2, varscan2
- ANGPT4 | c.242A>G p.K81R | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ANK2 | c.11290T>C p.S3764P | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARGLU1 | c.751_753del p.E251del | In Frame Del (DEL) | VAF 21/51 reads (41%) | called by pindel, varscan2
- ARPP21 | c.1996A>G p.R666G | Missense Mutation (SNP) | VAF 86/152 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BHLHE40 | c.858dup p.T287Hfs*11 | Frame Shift Ins (INS) | VAF 46/206 reads (22%) | called by mutect2, varscan2
- C6orf47 | c.423_427del p.G142Pfs*7 | Frame Shift Del (DEL) | VAF 37/146 reads (25%) | called by mutect2, pindel, varscan2
- C9orf64 | c.174G>T p.R58S | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CACNA2D1 | c.518A>T p.Y173F | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DCTN4 | c.740A>G p.Q247R | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GPATCH1 | c.740T>A p.L247Q | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- GRSF1 | c.1258-3T>G | Splice Region (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, varscan2
- IGHV2-70D | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | called by muse, varscan2
- IGHV3-23 | c.185del p.K62Rfs*22 | Frame Shift Del (DEL) | VAF 83/404 reads (21%) | called by pindel, varscan2
- IGHV3-7 | c.314T>C p.L105P | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- IGHV3-7 | c.19T>C p.W7R | Missense Mutation (SNP) | VAF 61/79 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRAG1 | c.2216C>G p.S739* | Nonsense Mutation (SNP) | VAF 26/117 reads (22%) | called by muse, mutect2, varscan2
- KLHL28 | c.1093A>G p.T365A | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- MLH1 | c.2123T>C p.I708T | Missense Mutation (SNP) | VAF 153/267 reads (57%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC2 | c.2797G>T p.D933Y | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- NSD1 | c.584A>C p.Y195S | Missense Mutation (SNP) | VAF 122/218 reads (56%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OR13C4 | c.245T>G p.L82R | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR1S2 | c.974T>C p.L325P | Missense Mutation (SNP) | VAF 157/291 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- PEDS1 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- RNF169 | c.1339C>T p.L447F | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SHOC1 | c.1367C>A p.S456Y | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SLC9C2 | c.1312T>C p.S438P | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SLF2 | c.3316T>C p.S1106P | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TLE5 | c.90A>T p.K30N | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRPM3 | c.3200-1G>A p.X1067_splice (on ENST00000357533 / NM_001366142.2; = p.X922_splice on NM_020952.6) | Splice Site (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- WNT9A | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF292 | c.3643A>T p.I1215L | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF878 | c.868A>C p.K290Q | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZZEF1 | c.3916C>T p.P1306S | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ANK3 | c.7746G>A p.K2582= | Silent (SNP) | VAF 77/156 reads (49%) | called by muse, mutect2, varscan2
- CNNM1 | c.1470C>T p.D490= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as rs766825296; called by muse, mutect2, varscan2
- CYP2U1 | c.723T>C p.F241= | Silent (SNP) | VAF 74/161 reads (46%) | called by muse, mutect2, varscan2
- FREM2 | c.3213A>C p.V1071= | Silent (SNP) | VAF 41/111 reads (37%) | called by muse, mutect2, varscan2
- FSIP2 | c.5853T>C p.A1951= | Silent (SNP) | VAF 24/98 reads (24%) | called by muse, mutect2, varscan2
- HIF1AN | c.24T>A p.A8= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as rs1193348477; called by muse, mutect2, varscan2
- WNT9A | c.336C>A p.A112= | Silent (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- ZNF516 | c.1293C>T p.A431= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs762139524, COSV71587656; called by muse, mutect2, varscan2
- ABL2 | c.*4224C>G | 3'UTR (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- ACVR1C | c.*398A>T | 3'UTR (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021375 C>G | 5'Flank (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- CD27 | c.137-53A>G | Intron (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- COL6A3 | c.*393T>C | 3'UTR (SNP) | VAF 30/38 reads (79%) | catalogued as rs1165908760; called by muse, mutect2, varscan2
- CSMD1 | chr8:2938023 G>T | 3'Flank (SNP) | VAF 25/64 reads (39%) | catalogued as rs1187038857; called by muse, mutect2, varscan2
- DLX6 | c.*456A>T | 3'UTR (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- E2F7 | c.*559C>T | 3'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- ENO2 | c.241-107C>T | Intron (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- ERCC6 | c.*1624T>C | 3'UTR (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- GGNBP2 | c.1641+21T>C | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- GINS2 | c.*1290A>G | 3'UTR (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- GNPDA2 | c.769+116T>A | Intron (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- GULP1 | c.844-2184A>C | Intron (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- HMGA1 | c.*1333dup | 3'UTR (INS) | VAF 19/82 reads (23%) | catalogued as rs931062273; called by mutect2, varscan2
- HPGD | chr4:174522522 C>T | 5'Flank (SNP) | VAF 4/26 reads (15%) | catalogued as rs1040540365; called by muse, mutect2
- IKZF3 | c.*6331A>G | 3'UTR (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- ITPR2 | c.*1010del | 3'UTR (DEL) | VAF 23/68 reads (34%) | catalogued as rs895474441; called by mutect2, varscan2
- KTI12 | c.*159G>C | 3'UTR (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- LINC02693 | chr17:21528264 G>T | 3'Flank (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
- MIR7162 | chr10:30364745 G>A | 3'Flank (SNP) | VAF 6/17 reads (35%) | catalogued as rs1477220533; called by muse, mutect2, varscan2
- MRTFB | c.1079+143A>G | Intron (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- MUC19 | n.20664-56C>A | Intron (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- NDUFS1 | c.*398G>A | 3'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- NEURL1B | c.*4339A>G | 3'UTR (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- OPCML | c.*4371A>G | 3'UTR (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- PA2G4 | c.*309C>G | 3'UTR (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- PDE10A | c.*3287del | 3'UTR (DEL) | VAF 29/84 reads (35%) | called by mutect2, pindel, varscan2
- PLEKHD1 | c.*52G>A | 3'UTR (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- PPP4R3A | chr14:91510268 G>A | 5'Flank (SNP) | VAF 37/107 reads (35%) | catalogued as rs1384274643; called by muse, mutect2, varscan2
- PSG4 | c.*246A>T | 3'UTR (SNP) | VAF 19/85 reads (22%) | called by muse, mutect2, varscan2
- SDCBP | c.-15-4059A>G | Intron (SNP) | VAF 33/101 reads (33%) | called by muse, mutect2, varscan2
- SLC26A2 | c.*3862G>A | 3'UTR (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2, varscan2
- SLC35G3 | c.*10T>C | 3'UTR (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- SPHKAP | c.*931A>G | 3'UTR (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- STMP1 | c.-35T>C | 5'UTR (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- SUSD6 | c.*3320T>G | 3'UTR (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- SYT10 | c.*1370A>G | 3'UTR (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- TAGAP | c.28-16A>C | Intron (SNP) | VAF 62/86 reads (72%) | called by muse, varscan2
- TCAIM | c.*313T>C | 3'UTR (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- TMEM50B | c.-42+944T>G | Intron (SNP) | VAF 16/244 reads (7%) | called by muse, mutect2
- TMSB4X | c.-17+171A>C | Intron (SNP) | VAF 37/44 reads (84%) | called by muse, mutect2, varscan2
- TRAPPC2L | c.*1202G>A | 3'UTR (SNP) | VAF 15/143 reads (10%) | called by muse, mutect2
- TRIAP1 | c.*26C>T | 3'UTR (SNP) | VAF 57/152 reads (38%) | catalogued as rs746454192, COSV56663760; called by muse, mutect2, varscan2
- TTYH3 | c.*709C>T | 3'UTR (SNP) | VAF 5/89 reads (6%) | catalogued as rs902740596, COSV51859159; called by muse, mutect2
- VEPH1 | c.529+608A>C | Intron (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- VSIG10 | c.*339A>G | 3'UTR (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- WWC1 | c.*3077A>G | 3'UTR (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- ZNF621 | c.*3009A>C | 3'UTR (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
